Somatic mutation profile of tumor specimen TARGET-30-PAUYDE-01A (aliquot TARGET-30-PAUYDE-01A-01D) from TARGET case TARGET-30-PAUYDE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 5.7 years (2,078 days).
Specimen TARGET-30-PAUYDE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af710096-d4fc-4eca-a56f-ffb2b50b1566.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUYDE-10A (Blood Derived Normal), aliquot TARGET-30-PAUYDE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b49146c5-c944-43f6-975d-e8f173fa775c

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIPOR1 | c.2602C>A p.P868T (on ENST00000379312 / NM_001193522.2; = p.P864T on NM_024519.4) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.44); catalogued as COSV50220602, COSV50241639; called by muse, mutect2, varscan2
- RYR1 | c.10501G>T p.D3501Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs763259167, CM112517, COSV62094176; called by muse, mutect2, varscan2
